Gene-level copy-number profile of tumor specimen TCGA-55-8204-01A from TCGA case TCGA-55-8204, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 87.1 years (31,818 days).
Specimen TCGA-55-8204-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.83aca67c-5e20-4603-98c1-2e1cbfc2d47d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8204-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8e65d20-6f0e-4f6b-9cbd-8acc56a631db

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13,017; copy number 3: 4,610; copy number 4: 35,296; copy number 5: 2,525; copy number 6: 3,358; copy number 7: 8; copy number 8: 19; copy number 9: 68; copy number 10: 145; copy number 12: 72; copy number 13: 59; copy number 15: 355; copy number 16: 283.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8204-01A-11D-2237-01): tumor purity 0.34, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 982 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–52,959,209, 743 genes, copy number 10–16 (within-gene range 2–16) (broad region; genes not listed).
- chr8:34,784,028–40,520,158, 112 genes, copy number 10 (broad region; genes not listed).
- chr14:22,066,016–22,509,406, 68 genes, copy number 9 (broad region; genes not listed).
- chr16:28,341,434–29,370,272, 59 genes, copy number 13 (within-gene range 3–13): AC009093.11, AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27, NUPR1, AC020765.6, AC020765.1, AC020765.2, SGF29, SULT1A2, AC020765.3, AC020765.4, SULT1A1, AC020765.5, NPIPB8, AC145285.4, EIF3C, CDC37P1, MIR6862-2, AC145285.5, NPIPB9, AC145285.7, AC145285.2, AC145285.1, AC145285.3, AC145285.6, ATXN2L, AC133550.2, TUFM, MIR4721, SH2B1, AC133550.3, ATP2A1, ATP2A1-AS1, AC133550.1, RABEP2, CD19, NFATC2IP, AC109460.2, MIR4517, AC109460.1, SPNS1, AC109460.3, LAT, AC109460.4, NPIPB10P, AC009093.3, RRN3P2, AC009093.9.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
